Somatic mutation profile of tumor specimen ALCH-B01Z-TTP1-A (aliquot ALCH-B01Z-TTP1-A-10-0-D-A657-36) from ALCHEMIST case ALCH-B01Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,709 days).
Specimen ALCH-B01Z-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3799cff-2896-4da6-a6d2-aad50d8bd34b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01Z-NB1-A (Blood Derived Normal), aliquot ALCH-B01Z-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/894e4561-1837-42aa-be3c-a6e3815e2e81

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 4, RNA 1, 3'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HECW2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53647672; called by muse, mutect2
- HSF4 | c.1391T>C p.L464P (on ENST00000521374 / NM_001040667.3; = p.L434P on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs577473154; called by muse, mutect2
- IGHD6-25 | c.1G>A p.G1R | Missense Mutation (SNP) | VAF 47/319 reads (15%) | catalogued as rs376836850; called by muse, mutect2
- KRT35 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs780571518, COSV55843170; called by muse, mutect2
- METTL7A | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs752350143; called by muse, mutect2
- MYO15A | c.4622C>T p.T1541M | Missense Mutation (SNP) | VAF 50/705 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780976475; called by muse, mutect2
- OR1J4 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100534316; called by muse, mutect2
- OR5H6 | c.926G>T p.R309I (on ENST00000642105; = p.R293I on NM_001005479.2) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101051771; called by muse, mutect2
- RPS6KA4 | c.1549G>T p.V517L | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53700523; called by muse, mutect2, varscan2
- VWF | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 29/385 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs1227726415; called by muse, mutect2
- AIPL1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 40/536 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2
- ATF7IP | c.1985_1989del p.K662Tfs*2 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | called by mutect2, pindel, varscan2
- BRD7 | c.432_441del p.M144Ifs*14 | Frame Shift Del (DEL) | VAF 89/357 reads (25%) | called by mutect2, pindel, varscan2
- CENPE | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAGLA | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2
- DZANK1 | c.1174T>A p.S392T (on ENST00000262547 / NM_001099407.1; = p.S193T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- ECHDC1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM98A | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- FBXL3 | c.917A>T p.Y306F | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- IQGAP3 | c.2361del p.F787Lfs*8 | Frame Shift Del (DEL) | VAF 109/535 reads (20%) | called by mutect2, pindel, varscan2
- ITLN1 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 40/308 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MESP2 | c.776del p.P259Rfs*222 | Frame Shift Del (DEL) | VAF 82/281 reads (29%) | called by mutect2, pindel, varscan2
- MRPS12 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA13 | c.1774G>C p.A592P | Missense Mutation (SNP) | VAF 100/432 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PCDHAC2 | c.2041G>T p.V681L | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.299); called by muse, mutect2
- PLP1 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SIN3B | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SKIV2L | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC44A5 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TEX11 | c.1019A>G p.N340S (on ENST00000344304; = p.N325S on NM_031276.3) | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CHSY3 | c.300C>T p.S100= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as rs887644318; called by muse, mutect2
- CLIC6 | c.2016C>T p.Y672= (on ENST00000360731 / NM_001317009.2; = p.Y654= on NM_053277.3) | Silent (SNP) | VAF 70/343 reads (20%) | called by muse, mutect2, varscan2
- ERN2 | c.2673C>T p.L891= | Silent (SNP) | VAF 40/576 reads (7%) | called by muse, mutect2
- GLP2R | c.60C>T p.G20= | Silent (SNP) | VAF 66/329 reads (20%) | catalogued as rs774643540; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 28/385 reads (7%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2
- REC8 | c.174C>T p.P58= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as rs756363583; called by muse, mutect2
- RNF2 | c.294A>G p.R98= | Silent (SNP) | VAF 85/671 reads (13%) | called by muse, mutect2, varscan2
- SERPINF1 | c.717G>A p.V239= | Silent (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- SRD5A3 | c.786C>A p.I262= | Silent (SNP) | VAF 82/332 reads (25%) | called by muse, mutect2, varscan2
- TRPM4 | c.9G>A p.V3= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- CFAP410 | c.144-1008G>A | Intron (SNP) | VAF 66/255 reads (26%) | catalogued as COSV100297244; called by muse, mutect2, varscan2
- NDUFA11 | chr19:5893113 T>C | 3'Flank (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- QRICH2 | c.*107G>T | 3'UTR (SNP) | VAF 61/162 reads (38%) | called by muse, mutect2, varscan2
- RPSAP52 | n.532G>T | RNA (SNP) | VAF 26/368 reads (7%) | catalogued as rs748668802; called by muse, mutect2
